Somatic mutation profile of tumor specimen MP2PRT-PAWCVA-TMP1-A (aliquot MP2PRT-PAWCVA-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAWCVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (916 days).
Specimen MP2PRT-PAWCVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f424678-caed-453e-aad7-226801552e8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCVA-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fd4eb4c-442b-4c46-8729-9645c0332538

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 3, Silent 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.1741C>T p.R581* (on ENST00000280758 / NM_001018072.2; = p.R118* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 158/392 reads (40%) | catalogued as COSV55032436; called by muse, mutect2, varscan2
- DGKH | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 185/431 reads (43%) | catalogued as COSV54943717; called by muse, mutect2, varscan2
- DGKI | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs774701094, COSV55953123; called by muse, mutect2, varscan2
- MYO18B | c.7444C>T p.R2482C | Missense Mutation (SNP) | VAF 174/404 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs780706076; called by muse, mutect2, varscan2
- TECRL | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as rs1440574072; called by muse, mutect2, varscan2
- U2AF2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 257/618 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs746794057; called by muse, mutect2, varscan2
- WIF1 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 117/287 reads (41%) | catalogued as rs373828974, COSV54129446; called by muse, mutect2, varscan2
- TMEM126A | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 103/207 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TRPM6 | c.3294G>T p.K1098N | Missense Mutation (SNP) | VAF 33/485 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ERICH6B | c.558G>A p.E186= | Silent (SNP) | VAF 224/644 reads (35%) | catalogued as COSV53918911; called by muse, mutect2
- HERC2 | c.576C>T p.L192= | Silent (SNP) | VAF 56/764 reads (7%) | catalogued as rs147414523; called by muse, mutect2
- CD72 | c.262+24_262+25dup | Intron (INS) | VAF 272/756 reads (36%) | called by mutect2, pindel, varscan2
- PEG10 | c.*234C>T | 3'UTR (SNP) | VAF 30/421 reads (7%) | called by muse, mutect2
